Surgical pathology report (de-identified scan), TCGA case TCGA-ZB-A96V, project TCGA-THYM (Thymoma), tissue source site Thoraxklinik, specimen TCGA-ZB-A96V-01A (Primary Tumor).

Name:

Identifier:

Unique Patient #:

Tumor Type : Thymoma

ICD-O-3

~~ICLF~~ Thymoma, type C 8586/3

~~path~~ Carcinoma, squamous cell NDS 8870/3

Site: Anterior mediastinum C38.1
JW 4/14/14

Pathology Report-Summary:

Material:

Tumor: 13.5 x 10.0 x 6.0 cm

Infiltration of capsule and fat tissue, and lung parenchyma

Diagnosis:

Squamous cell carcinoma of the thymus

pT3, pN1

Masaoka: IVb

Immunohistochemistry

tumor cells positive for: strong CD117, moderately positive for CD5

CD5-positive lymphocytes, negative for CD1a, CD99, and TdT

Source: NCI Genomic Data Commons file e8fb94c3-33ec-4ed5-a1f6-9b9261e6956f (TCGA-ZB-A96V.215F37AE-8910-41F9-95F9-E58E47F4E667.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).